Somatic mutation profile of tumor specimen 0DWWN5 from CCDI case PBCPRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical meningioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,290 days).
Specimen 0DWWN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f50cc06-e54d-4b58-84ba-a5011df21b2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWMG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73729421-34f4-4669-abd2-dcfa13bdc033

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- NF2 | c.920_923del p.F307* | Frame Shift Del (DEL) | VAF 105/157 reads (67%) | called by mutect2, pindel, varscan2
- OR2AK2 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- GREB1L | c.399T>C p.C133= | Silent (SNP) | VAF 79/229 reads (34%) | called by muse, mutect2, varscan2
- NPAP1 | c.1926A>G p.E642= | Silent (SNP) | VAF 125/288 reads (43%) | called by muse, mutect2, varscan2
- RALYL | c.-24+629T>G | Intron (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2
